Somatic mutation profile of tumor specimen ALCH-B2AL-TTP1-A (aliquot ALCH-B2AL-TTP1-A-2-0-D-A77J-36) from ALCHEMIST case ALCH-B2AL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.1 years (21,945 days).
Specimen ALCH-B2AL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4082be0b-24dc-4ffc-8a86-4688fda83ff5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2AL-NB1-A (Blood Derived Normal), aliquot ALCH-B2AL-NB1-A-1-0-D-A77J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1e395de-bb4e-490f-b8c4-212130341228

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STYX | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 14/220 reads (6%) | catalogued as rs931639551, COSV63462613; called by muse, mutect2
- CEP120 | c.1505A>G p.E502G | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- SLC9C1 | c.2270C>A p.A757E | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.022); called by muse, mutect2
- HSPA12B | c.1980C>A p.G660= | Silent (SNP) | VAF 2/14 reads (14%) | called by muse, mutect2
